Somatic mutation profile of tumor specimen TCGA-G4-6317-01A (aliquot TCGA-G4-6317-01A-11D-1719-10) from TCGA case TCGA-G4-6317, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 51.5 years (18,822 days).
Specimen TCGA-G4-6317-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b2891830-0996-4dc1-86cd-486af705f5d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G4-6317-10A (Blood Derived Normal), aliquot TCGA-G4-6317-10A-01D-1720-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ba730546-9006-4745-8dea-27c385dc1597

The open-access MAF lists 112 somatic variants for this specimen: 77 protein-altering or splice-affecting, 32 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 32, Nonsense Mutation 6, Splice Site 3, Frame Shift Del 3, 5'Flank 2, Frame Shift Ins 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3871C>T p.Q1291* | Nonsense Mutation (SNP) | VAF 25/104 reads (24%) | catalogued as rs1561588104, CM021065, CM053765, COSV57321476, COSV57325789, COSV57375930; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNQ2 | c.430C>T p.R144W | Missense Mutation (SNP) | VAF 64/363 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555873985, COSV60432857; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 75/101 reads (74%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABI3BP | c.551T>G p.L184R | Missense Mutation (SNP) | VAF 349/434 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1260464587, COSV52552852; called by muse, mutect2, varscan2
- ADNP | c.1955C>T p.T652M | Missense Mutation (SNP) | VAF 30/256 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1439145693, COSV100823884; called by muse, mutect2, varscan2
- AKT3 | c.1433G>A p.R478Q | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.413); catalogued as rs751275167, COSV55615010; called by muse, mutect2, varscan2
- ANAPC7 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 64/122 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as rs768592404, COSV71443990; called by muse, mutect2, varscan2
- APC | c.3631_3632del p.M1211Vfs*5 | Frame Shift Del (DEL) | VAF 31/87 reads (36%) | catalogued as rs1554085190; called by pindel, varscan2
- ATRIP | c.1267G>A p.V423I | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs1413281280, COSV99604222; called by muse, mutect2
- BTBD2 | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 34/54 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55307246; called by muse, mutect2, varscan2
- C11orf68 | c.488G>A p.R163H (on ENST00000530188; = p.R204H on NM_031450.4) | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as COSV56989970; called by muse, mutect2, varscan2
- C16orf46 | c.128G>A p.C43Y | Missense Mutation (SNP) | VAF 114/270 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs950606310, COSV55153533; called by muse, mutect2, varscan2
- CCDC88B | c.758C>T p.S253L | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.198); catalogued as COSV57266569; called by muse, mutect2, varscan2
- CDC37L1 | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 59/126 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs756219911, COSV67866448; called by muse, mutect2, varscan2
- CHD1L | c.242C>T p.T81I | Missense Mutation (SNP) | VAF 109/206 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV63615492; called by muse, mutect2, varscan2
- COL23A1 | c.805G>T p.E269* | Nonsense Mutation (SNP) | VAF 80/185 reads (43%) | catalogued as COSV66799555; called by muse, mutect2, varscan2
- COL7A1 | c.7522-2A>T p.X2508_splice | Splice Site (SNP) | VAF 90/109 reads (83%) | catalogued as COSV60403964; called by muse, mutect2, varscan2
- DLL1 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 59/163 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.436); catalogued as rs761280644, COSV64538934; called by muse, mutect2, varscan2
- DRAXIN | c.709G>T p.D237Y | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53845554; called by muse, mutect2, varscan2
- EPB41L5 | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 73/176 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55358558; called by muse, mutect2, varscan2
- ESYT1 | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 45/153 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs570468342, COSV57274967; called by muse, mutect2, varscan2
- EZHIP | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 85/158 reads (54%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV57957527; called by muse, mutect2, varscan2
- FAT3 | c.11821C>T p.R3941C | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.984); catalogued as COSV53104015, COSV53105667; called by muse, mutect2, varscan2
- HYDIN | c.14080C>T p.R4694C | Missense Mutation (SNP) | VAF 122/318 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.827); catalogued as rs201961276; called by muse, mutect2, varscan2
- IFI35 | c.93G>C p.K31N | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.093); catalogued as rs748648651, COSV55897067; called by muse, mutect2, varscan2
- IL6ST | c.631C>T p.H211Y | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.75); catalogued as COSV61143114; called by muse, mutect2, varscan2
- IL7R | c.568C>T p.L190F | Missense Mutation (SNP) | VAF 74/134 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.556); catalogued as rs1393411030, COSV57414250; called by muse, mutect2, varscan2
- INSL6 | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.511); catalogued as COSV67563562; called by muse, mutect2, varscan2
- INTS3 | c.1076C>T p.P359L | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59681926; called by muse, mutect2, varscan2
- IRAK1 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57657547; called by muse, mutect2
- KANK4 | c.211C>T p.R71* | Nonsense Mutation (SNP) | VAF 40/156 reads (26%) | catalogued as rs773572745, COSV62989628; called by muse, mutect2, varscan2
- KIAA0319 | c.3081G>A p.M1027I | Missense Mutation (SNP) | VAF 13/179 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100985847; called by muse, mutect2
- KLK6 | c.85G>T p.D29Y | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV59565347, COSV59566849; called by muse, mutect2, varscan2
- KTI12 | c.254A>G p.K85R | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as rs200200454; called by muse, mutect2, varscan2
- L3MBTL4 | c.1669G>A p.G557S | Missense Mutation (SNP) | VAF 68/97 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53142598; called by muse, varscan2
- LPAR3 | c.275C>T p.P92L | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV65455271; called by muse, mutect2, varscan2
- MAGEB6B | c.35G>A p.R12H | Missense Mutation (SNP) | VAF 67/129 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.765); catalogued as rs767190690; called by muse, mutect2, varscan2
- MAGI2 | c.220G>A p.V74M | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62702213; called by muse, mutect2, varscan2
- MAP1B | c.1975G>T p.E659* | Nonsense Mutation (SNP) | VAF 115/195 reads (59%) | catalogued as COSV57096640; called by muse, mutect2, varscan2
- MINAR1 | c.475C>T p.R159W | Missense Mutation (SNP) | VAF 19/23 reads (83%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as rs141472919, COSV59587069; called by muse, mutect2, varscan2
- NUP98 | c.3296G>A p.S1099N (on ENST00000359171 / NM_001365126.1; = p.S1082N on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 75/134 reads (56%) | SIFT tolerated (0.3); PolyPhen benign (0.223); catalogued as rs531135821, COSV61439442; called by muse, mutect2, varscan2
- ONECUT3 | c.1229G>A p.R410H | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as rs1261022700, COSV66640701; called by muse, mutect2, varscan2
- ORC2 | c.739C>T p.H247Y | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV52241888; called by muse, mutect2, varscan2
- OSR2 | c.867C>A p.C289* (on ENST00000297565 / NM_001142462.3; = p.A262E on NM_053001.3) | Nonsense Mutation (SNP) | VAF 149/206 reads (72%) | catalogued as COSV52559281; called by muse, mutect2, varscan2
- PCDHGA9 | c.1960C>G p.L654V | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV54043794; called by muse, mutect2, varscan2
- PCDHGB5 | c.1464G>A p.M488I | Missense Mutation (SNP) | VAF 51/97 reads (53%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV54043786; called by muse, mutect2, varscan2
- PIPOX | c.676G>A p.V226M | Missense Mutation (SNP) | VAF 229/813 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1371903925, COSV60143951; called by muse, mutect2, varscan2
- POLR1A | c.2395G>T p.V799L | Missense Mutation (SNP) | VAF 51/106 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.098); catalogued as COSV55697776, COSV99808556; called by muse, mutect2, varscan2
- PRDM10 | c.2000C>T p.S667L | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as rs1338852986, COSV58801688; called by muse, mutect2, varscan2
- PSMA1 | c.266G>T p.R89L | Missense Mutation (SNP) | VAF 57/143 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV67166223; called by muse, mutect2, varscan2
- RASA3 | c.1523C>T p.T508M | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs200485426; called by muse, mutect2, varscan2
- RBM17 | c.930+2T>C p.X310_splice | Splice Site (SNP) | VAF 16/48 reads (33%) | catalogued as COSV65915089; called by muse, mutect2, varscan2
- RGL2 | c.608del p.G203Afs*49 | Frame Shift Del (DEL) | VAF 15/54 reads (28%) | catalogued as rs762949421; called by mutect2, varscan2
- RORA | c.179C>T p.T60M | Missense Mutation (SNP) | VAF 50/69 reads (72%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.472); catalogued as rs188796486, COSV59546707; called by muse, mutect2, varscan2
- RP1L1 | c.2504A>G p.Q835R | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV101223692; called by muse, mutect2
- RYR1 | c.10090C>T p.R3364W | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as COSV62103975; called by muse, mutect2, varscan2
- RYR2 | c.12188C>T p.T4063M | Missense Mutation (SNP) | VAF 44/71 reads (62%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.787); catalogued as rs1214925323, COSV63665103; called by muse, mutect2, varscan2
- SCN5A | c.4876C>T p.R1626C (on ENST00000333535 / NM_198056.3; = p.R1625C on NM_000335.5) | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs918933961, COSV61118793; ClinVar: uncertain significance; called by muse, mutect2
- SERPINH1 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.77); PolyPhen benign (0.022); catalogued as rs1296984761, COSV63998730; called by muse, mutect2, varscan2
- SLC1A6 | c.341C>T p.T114I | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as COSV55674588; called by muse, mutect2, varscan2
- SLITRK3 | c.1793C>T p.T598M | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.176); catalogued as rs772285952, COSV53854069; called by muse, mutect2, varscan2
- SPIRE1 | c.1151G>A p.R384Q | Missense Mutation (SNP) | VAF 63/84 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1475654330, COSV100563779, COSV59152151; called by muse, mutect2, varscan2
- SRD5A2 | c.604A>T p.I202F | Missense Mutation (SNP) | VAF 104/272 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99252639; called by muse, mutect2, varscan2
- STOX1 | c.1895G>A p.G632E | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs1372051518, COSV53818390; called by muse, mutect2, varscan2
- STYX | c.599-1G>A p.X200_splice | Splice Site (SNP) | VAF 62/168 reads (37%) | catalogued as COSV53592537; called by muse, mutect2, varscan2
- TCF7L2 | c.1258C>T p.R420W (on ENST00000355995 / NM_001367943.1; = p.R397W on NM_030756.5) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53335898; called by mutect2, varscan2
- TCFL5 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV53899439; called by muse, mutect2, varscan2
- TNXB | c.8086G>A p.D2696N (on ENST00000647633; = p.D2449N on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.358); catalogued as COSV64485876; called by muse, mutect2, varscan2
- TPO | c.2329C>T p.R777W | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.394); catalogued as rs745501383, COSV61101004; called by muse, mutect2, varscan2
- TTC33 | c.85G>T p.E29* | Nonsense Mutation (SNP) | VAF 48/187 reads (26%) | catalogued as COSV61803045; called by muse, varscan2
- TTN | c.61235A>T p.Y20412F (on ENST00000591111; = p.Y12988F on NM_003319.4) | Missense Mutation (SNP) | VAF 70/181 reads (39%) | PolyPhen benign (0.003); catalogued as COSV60382227; called by muse, mutect2, varscan2
- TTYH1 | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT tolerated (1); PolyPhen possibly damaging (0.789); catalogued as rs758898025, COSV56615927; called by muse, varscan2
- TULP2 | c.1321G>C p.G441R | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.133); catalogued as COSV55480430, COSV99667649; called by muse, mutect2, varscan2
- TXLNA | c.26G>A p.G9E | Missense Mutation (SNP) | VAF 107/188 reads (57%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.084); catalogued as rs1393378048, COSV65315283; called by muse, mutect2, varscan2
- EIF2B1 | c.227_229del p.I76del | In Frame Del (DEL) | VAF 20/40 reads (50%) | called by pindel, varscan2
- FADS2 | c.1216_1217del p.L406Mfs*7 | Frame Shift Del (DEL) | VAF 8/54 reads (15%) | called by pindel, varscan2
- MAP3K21 | c.850dup p.T284Nfs*40 | Frame Shift Ins (INS) | VAF 52/140 reads (37%) | called by pindel, varscan2*
- C1RL | c.1275G>A p.E425= | Silent (SNP) | VAF 83/161 reads (52%) | catalogued as COSV56926971; called by muse, mutect2, varscan2
- CASKIN1 | c.984G>T p.R328= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV58877591; called by muse, mutect2, varscan2
- ELMOD1 | c.222C>T p.P74= | Silent (SNP) | VAF 65/143 reads (45%) | catalogued as rs749048141, COSV56194383; called by muse, mutect2, varscan2
- GNAS | c.954C>T p.V318= | Silent (SNP) | VAF 29/133 reads (22%) | catalogued as COSV100007871; called by muse, mutect2, varscan2
- GTF2IRD2 | c.1887C>T p.N629= | Silent (SNP) | VAF 55/234 reads (24%) | catalogued as rs1278483770, COSV63100669; called by mutect2, varscan2
- HDGFL1 | c.321G>A p.P107= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as rs1288711494, COSV57753233; called by muse, mutect2, varscan2
- HMCN1 | c.13242C>T p.A4414= | Silent (SNP) | VAF 63/115 reads (55%) | catalogued as rs1399317038, COSV54945631; called by muse, mutect2, varscan2
- INHBE | c.564G>C p.L188= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as COSV99875389; called by muse, mutect2, varscan2
- KCNK10 | c.87C>T p.N29= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as rs747542447, COSV56646262; called by muse, mutect2, varscan2
- MAGEB3 | c.117C>A p.S39= | Silent (SNP) | VAF 114/424 reads (27%) | catalogued as COSV64396756; called by muse, mutect2, varscan2
- NBEA | c.3573C>T p.T1191= | Silent (SNP) | VAF 34/80 reads (43%) | catalogued as rs755124584, COSV100077281; called by muse, mutect2, varscan2
- NCOR1 | c.4629C>T p.S1543= | Silent (SNP) | VAF 61/83 reads (73%) | catalogued as COSV51998857; called by muse, mutect2, varscan2
- NTSR1 | c.426C>T p.R142= | Silent (SNP) | VAF 68/107 reads (64%) | catalogued as rs531921966, COSV100980736, COSV65139714; called by muse, mutect2, varscan2
- OR10H1 | c.747G>A p.V249= | Silent (SNP) | VAF 35/139 reads (25%) | catalogued as COSV58473221; called by muse, mutect2, varscan2
- OR2D2 | c.765A>T p.A255= | Silent (SNP) | VAF 25/102 reads (25%) | catalogued as COSV55058413; called by muse, mutect2, varscan2
- OR2L8 | c.750C>T p.Y250= | Silent (SNP) | VAF 99/195 reads (51%) | catalogued as COSV61728611; called by muse, mutect2, varscan2
- OR4S2 | c.18C>T p.N6= | Silent (SNP) | VAF 43/139 reads (31%) | catalogued as rs1281742838, COSV56745922, COSV56748516; called by muse, mutect2, varscan2
- OSGEP | c.381C>T p.T127= | Silent (SNP) | VAF 42/89 reads (47%) | catalogued as rs774022048, COSV52834033; called by muse, mutect2, varscan2
- PCDHA12 | c.1608C>T p.S536= | Silent (SNP) | VAF 17/27 reads (63%) | catalogued as COSV56491146; called by muse, mutect2, varscan2
- PDHA2 | c.24C>T p.R8= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as rs745370766, COSV54778156; called by muse, mutect2, varscan2
- RET | c.3090C>T p.D1030= | Silent (SNP) | VAF 31/74 reads (42%) | catalogued as rs142859395; ClinVar: likely benign; called by muse, mutect2, varscan2
- SON | c.1629G>T p.T543= | Silent (SNP) | VAF 25/48 reads (52%) | catalogued as rs367848437, COSV51671526; called by muse, mutect2, varscan2
- SORCS1 | c.1272C>T p.F424= | Silent (SNP) | VAF 27/111 reads (24%) | catalogued as rs374656899; called by muse, mutect2, varscan2
- TASOR2 | c.876C>T p.D292= | Silent (SNP) | VAF 53/406 reads (13%) | catalogued as rs200764347, COSV60169858; called by muse, mutect2, varscan2
- TENM1 | c.2817C>T p.F939= | Silent (SNP) | VAF 79/195 reads (41%) | catalogued as rs746512976, COSV64430306; called by muse, mutect2, varscan2
- TMC6 | c.693C>G p.R231= | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as COSV59811963; called by muse, mutect2, varscan2
- TNC | c.3981C>T p.H1327= | Silent (SNP) | VAF 39/74 reads (53%) | catalogued as rs750137926, COSV60785368, COSV60791230; called by muse, mutect2, varscan2
- TRIO | c.2091C>T p.D697= | Silent (SNP) | VAF 59/112 reads (53%) | catalogued as rs778327240, COSV60079873; called by muse, mutect2, varscan2
- UNC13C | c.3120A>G p.R1040= | Silent (SNP) | VAF 17/138 reads (12%) | catalogued as COSV52929254; called by muse, mutect2, varscan2
- WDR25 | c.882A>C p.A294= | Silent (SNP) | VAF 55/122 reads (45%) | catalogued as COSV58940338; called by muse, mutect2, varscan2
- ZFAND2B | c.357C>T p.S119= | Silent (SNP) | VAF 64/155 reads (41%) | catalogued as COSV54701340; called by muse, mutect2, varscan2
- ZNF430 | c.519G>A p.Q173= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as COSV55113001; called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840199 G>A | 5'Flank (SNP) | VAF 6/104 reads (6%) | catalogued as rs1190126697, COSV58339528; called by muse, mutect2
- AL132655.6 | chr20:58840793 G>A | 5'Flank (SNP) | VAF 36/72 reads (50%) | catalogued as rs1408655246, COSV58328981; called by muse, varscan2
- PCDHGA2 | c.2424+25G>A | Intron (SNP) | VAF 48/100 reads (48%) | catalogued as COSV54011933; called by muse, mutect2, varscan2
